Somatic mutation profile of tumor specimen TCGA-3H-AB3S-01A (aliquot TCGA-3H-AB3S-01A-21D-A39R-32) from TCGA case TCGA-3H-AB3S, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 69.7 years (25,471 days).
Specimen TCGA-3H-AB3S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a74ec23c-8ce0-49e7-928c-096e6b8034d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3H-AB3S-10A (Blood Derived Normal), aliquot TCGA-3H-AB3S-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/050f3314-f6ce-490f-b7b2-338dac1beef0

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs765028814; called by muse, mutect2, varscan2
- ARHGAP32 | c.4630G>T p.A1544S (on ENST00000310343 / NM_001378025.1; = p.A1195S on NM_014715.4) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs756000808, COSV59844185; called by muse, mutect2, varscan2
- ARHGEF10 | c.3723C>A p.D1241E (on ENST00000398564; = p.D1216E on NM_014629.4) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as COSV50695533; called by muse, mutect2, varscan2
- HR | c.2203+1del p.X735_splice | Splice Site (DEL) | VAF 7/31 reads (23%) | catalogued as rs1261719822; called by mutect2, pindel
- ITLN2 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs777694118, COSV100600709; called by muse, mutect2, varscan2
- KCNJ15 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60811089; called by muse, mutect2, varscan2
- MIXL1 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 116/424 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100830808; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64056870; called by muse, mutect2, varscan2
- NCKAP5 | c.5143A>T p.M1715L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1477206391; called by muse, mutect2, varscan2
- NPHP1 | c.1839C>G p.F613L (on ENST00000393272 / NM_207181.4; = p.F614L on NM_000272.5) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100338449; called by muse, mutect2, varscan2
- PBRM1 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV56308731; called by muse, varscan2
- SLC10A5 | c.649G>C p.G217R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72828470; called by muse, mutect2, varscan2
- SLCO5A1 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52653409; called by muse, mutect2, varscan2
- TMEM9B | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.176); catalogued as rs987818311; called by muse, mutect2, varscan2
- ENAM | c.1324G>C p.G442R | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- FAM184A | c.2356G>C p.D786H | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FANCI | c.912C>A p.N304K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- HOXB1 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INO80 | c.749T>A p.V250D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- MGA | c.4008dup p.E1337* | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- MMP8 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.02); called by muse, mutect2
- OR2T4 | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR52A1 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PKM | c.154+1G>T p.X52_splice | Splice Site (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.2339C>G p.T780S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC10A5 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC44A4 | c.414del p.V139Sfs*18 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | called by mutect2, pindel, varscan2
- SPATA16 | c.1496C>A p.A499E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- TAC1 | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TMEM132A | c.1604G>T p.R535L (on ENST00000453848 / NM_178031.3; = p.R536L on NM_017870.4) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.209); called by muse, varscan2
- VWA3B | c.239C>G p.A80G | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.194); called by muse, varscan2
- ZNF225 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- C1QTNF4 | c.546G>T p.A182= | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- CACNA1H | c.3729C>T p.D1243= | Silent (SNP) | VAF 46/355 reads (13%) | catalogued as rs780289958, COSV62003738; called by muse, mutect2, varscan2
- EIF3J | c.729T>C p.Y243= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, varscan2
- FREM2 | c.2052C>A p.S684= | Silent (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- KRT2 | c.1324T>C p.L442= | Silent (SNP) | VAF 71/205 reads (35%) | catalogued as rs985667573; called by muse, mutect2, varscan2
- KRT33A | c.915C>G p.A305= | Silent (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- LGI1 | c.159T>G p.A53= | Silent (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- MUC16 | c.35130T>C p.H11710= | Silent (SNP) | VAF 81/162 reads (50%) | catalogued as rs1466105423; called by muse, mutect2, varscan2
- MUC5B | c.9447C>G p.G3149= | Silent (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- OR2T4 | c.195G>T p.V65= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs774372333; called by muse, mutect2, varscan2
- SMAD9 | c.333G>A p.E111= | Silent (SNP) | VAF 69/179 reads (39%) | called by muse, mutect2, varscan2
- TENM3 | c.3039G>A p.G1013= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs774232413; called by muse, mutect2, varscan2
- TTN | c.45888C>T p.S15296= (on ENST00000591111; = p.S7872= on NM_003319.4) | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs780845171, COSV100636157; called by muse, mutect2, varscan2
- ZSCAN21 | c.*258_*260dup | 3'UTR (INS) | VAF 56/128 reads (44%) | called by mutect2, pindel, varscan2
